Surgical pathology report (de-identified scan), TCGA case TCGA-24-1614, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1614-01A (Primary Tumor).

[page 1 of 6]
SURGICAL PATHOLOGY REPORT

Patient Name
Address: Service Accession #:
Location Taken:
Gender: MRN: Received:
DOB: Hospital # Reported:
Patient Type

Physician(s):

Other Related Clinical Data:

TCGA-24-1614

DIAGNOSIS:

OMENTUM, OMENTECTOMY

- PAPILLARY SEROUS ADENOCARCINOMA

OMENTUM, BIOPSY

- PAPILLARY SEROUS ADENOCARCINOMA

SOFT TISSUE "UPPER ABDOMINAL MASS," EXCISION

- PANCREAS WITH PSEUDOCYST, CHRONIC PANCREATITIS AND FOCAL ISLET CELL HYPERPLASIA

-- NO CARCINOMA IDENTIFIED

MESENTERY, SIGMOID, EXCISION

- PAPILLARY SEROUS ADENOCARCINOMA

OVARY, RIGHT, SALPINGO-OOPHORECTOMY

- NO CARCINOMA IDENTIFIED

- PARAOVARIAN ADHESIONS

FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY

- ADENOCARCINOMA IN-SITU (SEE COMMENT)

- NUMEROUS DETACHED LUMINAL FRAGMENTS OF ADENOCARCINOMA

OVARY, LEFT, SALPINGO-OOPHORECTOMY

- PAPILLARY SEROUS ADENOCARCINOMA (SEE COMMENT)

- PAPILLARY SEROUS ADENOCARCINOMA INVOLVING PARAOVARIAN SOFT TISSUE

FALLOPIAN TUBE, LEFT SALPINGO-OOPHORECTOMY

- NUMEROUS DETACHED LUMINAL FRAGMENTS OF ADENOCARCINOMA

UTERUS, CERVIX, TOTAL ABDOMINAL HYSTERECTOMY

- NO HISTOPATHOLOGIC ABNORMALITY

[page 2 of 6]
[REDACTED]

UTERUS, ENDOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY
- SINGLE FOCUS OF ENDOMETRIAL INTRAEPITHELIAL CARCINOMA (SEE COMMENT)

UTERUS, MYOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY
- FOCAL ADENOMYOSIS

UTERUS, SEROSA, TOTAL ABDOMINAL HYSTERECTOMY
- PAPILLARY SEROUS ADENOCARCINOMA

[REDACTED] By this signature, I attest that the above diagnosis is based upon my
personal
examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By [REDACTED]

Intraoperative Consultation:

FS1: Omentum biopsy

- "Poorly differentiated carcinoma with papillary features," [REDACTED]

FS2: Upper abdominal mass

- "Pancreatic tissue with pseudocyst," [REDACTED]

[REDACTED]

Microscopic Description and Comment:

The bulk of the tumor in this case is present in the omentum which is largely replaced by papillary serous adenocarcinoma. The sigmoid mesentery also contains a small amount of papillary serous adenocarcinoma. The ovaries and endometrium have been entirely submitted for histologic evaluation. A small amount of papillary serous adenocarcinoma is present on the left ovary (2 mm) and in left paraovarian soft tissue. Sections of both fallopian tubes show numerous, small, detached fragments of adenocarcinoma in the lumens but no invasive carcinoma is present in either tube. A single, small focus of in situ adenocarcinoma is present in the right fallopian tube. Sections of endometrium show a single focus of endometrial intraepithelial carcinoma involving a single gland (slide E14). No invasive serous carcinoma was present in the endometrium. The pancreatic biopsy shows a pseudocyst with surrounding chronic pancreatitis and a small amount of islet cell hyperplasia. No pancreatic carcinoma is identified.

In summary, I believe this case is best classified as primary peritoneal papillary serous carcinoma with small foci of in-situ serous carcinoma involving the fallopian tube and endometrium. Others have raised the possibility that even non-invasive serous carcinoma in the endometrium may be the source of extrauterine spread.

Reference:

[REDACTED]

History:

The patient is a [REDACTED] with endometrial/ovarian carcinoma, postmenopausal bleeding and 4 liters of ascites. Operative procedure: Laparotomy, omentectomy, total abdominal hysterectomy, bilateral salpingo-oophorectomy, sigmoid mesentery biopsy.

[page 3 of 6]
Specimen(s) Received:

A: OMENTUM, ROUTINE
B: OMENTUM, ROUTINE
C: UPPER ABDOMINAL MASS
D: SIGMOID-MESENTERY
E: UTERUS, CERVIX, TUBES AND OVARIES

Gross Description

Received are five containers of formalin labeled with the patient's name. The first contains a piece of omentum measuring 52 x 19 x 3 cm, greater than 90% of which is replaced by firm, white carcinoma. Also received are multiple small fragments of fat measuring 16.5 x 11 x 3.5 cm in aggregate. Each of these pieces is also involved by carcinoma. Labeled A1-A4 - sections of large piece of omentum; A5 - sections through smaller piece of omentum.

The second container is labeled "omentum, FS1/X1." It contains a white cassette labeled "FS1" with a piece of white tissue measuring 1.9 x 1.1 x 0.3 cm. Labeled B1. Also within the container are four pieces of fatty tissue measuring 11.1 x 10.0 x 1.3 cm in aggregate studded with numerous white nodules measuring up to 3.0 x 1.5 x 0.9 cm, consistent with metastatic tumor.

The third container is labeled "#3, upper abdominal mass, FS2." It contains a white cassette labeled "FS2" in which there are three pieces of white-to-tan tissue measuring 1.0 x 0.5 x 0.2 cm, 0.8 x 0.5 x 0.3 cm, and 0.9 x 0.9 x 0.3 cm. The cut surface of the largest piece appears cystic and filled with brown material. Labeled C1. Also within the container is a piece of white-to-tan tissue measuring 1.4 x 0.7 x 0.2 cm.

The fourth container is labeled "#4, sigmoid mesentery." It contains seven pieces of grey-tan tissue ranging from 0.2 x 0.2 x 0.1 cm to 1.8 x 1.0 x 0.4 cm. The four smallest pieces are wrapped.

The fifth container is labeled "uterus, cervix, both tubes and ovaries." It contains a previously opened uterus measuring 8.5 cm fundus to os x 4 cm cornu to cornu x 5.3 cm anterior to posterior. The cervix measures 2.5 x 2.5 cm and is unremarkable. The endocervical canal measures 3.2 x 0.5 cm and is unremarkable. The endometrial cavity measures 3.4 x 2.0 cm and is lined by white endometrium measuring 0.1 cm in thickness with no focal lesions. The myometrium measures 2.3 cm in thickness. The right fallopian tube measures 3.7 cm in length x 0.7 cm in diameter and ends in unremarkable fimbriae. The right ovary measures 2.0 x 1.5 x 1.0 cm. Sections show corpora albicantia. The left fallopian tube measures 4.5 cm in length x 0.8 cm in diameter and ends with unremarkable fimbriae. The left ovary measures 2.7 x 1.2 x 1.0 cm. Sections show corpora albicantia and small hemorrhagic cysts measuring 0.1 cm at the hilum, suggestive of veins vs. endometriosis. The posterior serosa shows white-brown pieces of tissue measuring up to 0.2 cm in greatest dimension, suggestive of either endometriosis or metastatic disease. The endometrium and both ovaries are entirely submitted for histologic evaluation. Labeled E1 - anterior cervix; E2 - anterior lower uterine segments and peritoneal reflection; E3 - anterior endomyometrium; E4 - anterior fundus; E5, E6 - anterior peritoneal reflection; E7 to E9 - remaining anterior endometrium; E10 - posterior cervix; E11 - posterior lower uterine segment and endometrium; E12 - posterior endometrium; E13 - posterior fundus; E14 through E16 - remainder of posterior endometrium; E17, E18 - right tube and ovary; E19, E20 - left ovary; E21 - left tube.

Synopsis

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN (PERITONEAL) NEOPLASMS

[page 4 of 6]
- [REDACTED]
- [REDACTED]
1. A neoplasm is PRESENT
2. The HISTOLOGIC DIAGNOSIS is:
Serous adenocarcinoma
3. The LOCATION(S) OF THE PRIMARY TUMOR(S) is/are:
PERITONEAL
5. The NUCLEAR (BRODERS') GRADE of the tumor is:
G3 (Poorly-differentiated)
6. Tumor IS identified on the ovarian surface(s).
- 7 Tumor DOES involve the mesovarium.
8. Tumor DOES involve the adjacent fallopian tube.
(in situ carcinoma only) (see comment)
9. Tumor invasion of pelvic soft tissue CANNOT BE EVALUATED.
10. Tumor involvement of the pelvic peritoneum is PRESENT.
11. Metastatic involvement of the EXTRAPELVIC PERITONEUM is PRESENT.
12. Metastatic involvement of the omentum is PRESENT.
13. The maximum dimension of tumor implants outside the true pelvis is 16.5 cm.
14. Metastatic involvement of the uterine serosa is PRESENT.
15. Involvement of the endometrium by endometrial intraepithelial carcinoma is present (see comment).
16. Regional lymph node metastases CANNOT BE EVALUATED.
17. The total number of regional lymph nodes examined is 0
19. DETAILED STAGING INFORMATION:

Based on the above information, the PRIMARY TUMOR is
classified as:

TNM Scheme	FIGO Scheme	Definition	
T3c	IIIC	Macroscopic peritoneal	
metastasis beyond true pelvis measuring > 2 cm in greatest dimension.			

THE REGIONAL LYMPH NODES are classified as:
NX (Nodal status cannot be assessed)

THE STATUS OF DISTANT TUMOR SITES is classified as:
MX (Status cannot be assessed)

20. The FINAL AJCC/UICC/FIGO STAGE IS:
AJCC/UICC/FIGO
X Insufficient data to assign stage

[page 5 of 6]
The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Source: NCI Genomic Data Commons file 54107acc-bc17-4d4f-9a40-fdbb5e3d76c7 (TCGA-24-1614.4E371C15-C0D1-454A-997D-DFBE98B02F7E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).